MMRF case MMRF_1945 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7964181c-916b-4d83-817a-4d6e489f94c9

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 44 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 44.2 years (16,151 days); ISS stage: III; Days to last known disease status: 59 days; Days to last follow up: 59 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (2 entries)
- Days to follow up: -2 days; ECOG performance status: 3.
- Follow-up contact recording only the day: day 59.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Platelets 185 ×10⁹/L.
- Calcium 2.35 mmol/L.
- M Protein 4.9 g/dL.
- Leukocytes 3.2 ×10⁹/L.
- Beta 2 Microglobulin 12.6 µg/mL.
- Blood Urea Nitrogen 7.5 mmol/L.
- Creatinine 108 µmol/L.
- Glucose 4.46 mmol/L.
- Absolute Neutrophil 1.4 ×10⁹/L.
- Immunoglobulin A 0.33 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 191 mg/dL.
- Hemoglobin 4.65 mmol/L.
- Immunoglobulin M 0.21 g/L.
- Total Protein 11 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL.
- Immunoglobulin G 67.9 g/L.
- Lactate Dehydrogenase 5.35 µkat/L.
- C-Reactive Protein 5.19 mg/dL.
- Albumin 30 g/L.

Other clinical attributes
- Day -2: Weight: 109 kg; Height: 163 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1945_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1945_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
